Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADK-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Op 5/20/14

CLINICAL DIAGNOSIS: R/O HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial resection of the mass located in the segment 3

Wedge resection of the mass located in the segment 7

Organ: Liver

Segment 3 (5.5 x 4.0 x 3.0 cm, 30.0 gm)

Segment 7 (4.0 x 2.0 x 1.5 cm, 10.9 gm)

Lesions:

[Mass 1]

Tumor location: Segment 3

Size: 3.5 x 2.5 x 2.5 cm

Cut surface: Well demarcated, pale tan, solid and lobulated mass

Gross type: Multinodular confluent

Extent: Bulging by mass, but smooth

Resection margin: Not involved, grossly (safety margin: 1.1 cm)

[Mass 2]

Tumor location: Segment 7

Size: 0.9 x 0.8 x 0.8 cm

Cut surface: Well demarcated, homogenous, pale tan and solid mass

Gross type: Multinodular confluent

Extent: Bulging by mass, but smooth

Resection margin: Not involved, grossly (safety margin: 0.6 cm)

Remaining parenchyme: Cirrhosis

Representative sections submitted

Gross photo: Present

Ink key:

Resection margins: Green

Capsular surface: Black

Blocks

T1-4, mass of segment 3 [Mass 1] x 4

T5-6, mass of segment 7 [Mass 2] x 2

RM, resection margin of segment 3 x 1

L, nontumorous liver parenchyme x 1

X1-2, fibrofatty tissue x 2

MICROSCOPIC:

[Mass 1]

Tumor location: Segment 3

Tumor type: Hepatocellular carcinoma

The worst differentiation III

The major differentiation III

Histologic type: Trabecular, insular

Cell type: Hepatic

Fatty change: Yes

[page 2 of 3]
Cholangiocarcinoma: No
Fibrous capsule formation: No
Septum formation: Yes
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Vascular invasion: Yes
Bile duct invasion: No
[Mass 2]

Tumor location: Segment 7
Tumor type: Hepatocellular carcinoma
The worst differentiation III
The major differentiation II
Histologic type: Trabecular
Cell type: Hepatic
Fatty change: Yes

Cholangiocarcinoma: No
Fibrous capsule formation: No
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme: Cirrhosis, mixed steatosis, mild

NOT reported. Gross:

Cervix, smear, inflammation, atrophy

Cervix, smear, inflammation, atrophy

Cervix, smear, inflammation, atrophy

Cervix, smear, inflammation

Cervix, smear, atrophy

Cervix, smear, atrophy

Cervix, smear, atrophy

stomach,body,scopic,erosion,chronic gastritis

Large intestine, ascending colon, ectomy, hyperplastic polyp

liver,resection,hepatocellular carcinoma
T56000, P17, M81703

DIAGNOSIS:

[page 3 of 3]
Liver, segment 3, partial resection:
Hepatocellular carcinoma

Liver, segment 7, wedge resection:
Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file c17546ac-1b18-4b08-9a80-2dba5cf701e6 (TCGA-DD-AADK.DD514735-20C6-49AE-BD02-5D08C6C61523.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).